Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7QW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7QW-01A (Primary Tumor).

ICD-3
Astrocytoma, grade III
Site ^{core} Brain, supratentorial
path ^{path} Brain, NOS
C71.0
C71.9
9/10/13

Glial tumor with astrocytic differentiation
IDH1 R132H mutation present
Increased proliferation (Ki67) and single mitoses detected

Diagnosis
anaplastic astrocytoma WHO grade III

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file ced0b919-0678-489e-abf4-2dd9b1feebbe (TCGA-S9-A7QW.76D9DFBD-70A4-4159-A6D3-66507BB4047E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).